Somatic mutation profile of tumor specimen HCM-BROD-0578-C15-06A (aliquot HCM-BROD-0578-C15-06A-01D-A83U-36) from HCMI case HCM-BROD-0578-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IV; Tumor grade: GX; Age at diagnosis: 46.7 years (17,054 days).
Specimen HCM-BROD-0578-C15-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4a78223e-f713-4ad4-ae90-49601c6aff08.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0578-C15-10A (Blood Derived Normal), aliquot HCM-BROD-0578-C15-10A-01D-A83U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8de98525-75ff-4f14-b5bb-2f29aa81d594

The open-access MAF lists 19 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 3, Nonsense Mutation 2, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALMS1 | c.9670G>T p.D3224Y | Missense Mutation (SNP) | VAF 16/374 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52506062; called by muse, mutect2
- CDH1 | c.763C>T p.Q255* | Nonsense Mutation (SNP) | VAF 27/587 reads (5%) | catalogued as COSV55727283; called by muse, mutect2
- DHX35 | c.1253C>T p.T418M | Missense Mutation (SNP) | VAF 22/314 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs376209770; called by muse, mutect2
- FBXO42 | c.1669C>T p.R557C | Missense Mutation (SNP) | VAF 44/656 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs565632708; called by muse, mutect2
- OR6T1 | c.526C>A p.H176N | Missense Mutation (SNP) | VAF 18/500 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1371737888; called by muse, mutect2
- BAIAP2L2 | c.630G>C p.Q210H | Missense Mutation (SNP) | VAF 19/634 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.553); called by muse, mutect2
- C7 | c.305T>C p.V102A | Missense Mutation (SNP) | VAF 12/332 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CCNB1 | c.802G>A p.D268N | Missense Mutation (SNP) | VAF 27/410 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- GRM8 | c.925G>C p.D309H | Missense Mutation (SNP) | VAF 18/410 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- LRP6 | c.2911G>C p.D971H | Missense Mutation (SNP) | VAF 20/403 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); called by muse, mutect2
- LTK | c.1117G>T p.V373L | Missense Mutation (SNP) | VAF 20/454 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- MYO16 | c.3818G>A p.W1273* | Nonsense Mutation (SNP) | VAF 32/924 reads (3%) | called by muse, mutect2
- PRRT4 | c.2401G>A p.V801I | Missense Mutation (SNP) | VAF 38/810 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.054); called by muse, mutect2
- TTC30A | c.686T>A p.M229K | Missense Mutation (SNP) | VAF 23/379 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2
- UTP20 | c.1251G>A p.Q417= | Splice Region (SNP) | VAF 11/304 reads (4%) | called by muse, mutect2
- CGAS | c.237C>T p.A79= | Silent (SNP) | VAF 40/882 reads (5%) | called by muse, mutect2
- HTRA4 | c.210C>T p.R70= | Silent (SNP) | VAF 32/890 reads (4%) | called by muse, mutect2
- PHF2 | c.1269G>A p.P423= | Silent (SNP) | VAF 18/472 reads (4%) | catalogued as COSV63683799; called by muse, mutect2
- CSNK2A1 | c.213+1497A>G | Intron (SNP) | VAF 22/393 reads (6%) | catalogued as rs192907725; called by muse, mutect2
